Somatic mutation profile of tumor specimen C3N-00646-01 (aliquot CPT0081970009) from CPTAC case C3N-00646, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.9 years (21,144 days).
Specimen C3N-00646-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac07a3fd-ccb6-4c77-9734-8a5156319797.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00646-71 (Blood Derived Normal), aliquot CPT0082030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c87818e-7820-4896-bc41-69ee81367812

The open-access MAF lists 125 somatic variants for this specimen: 89 protein-altering or splice-affecting, 14 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 14, Frame Shift Del 13, Intron 7, 3'UTR 6, Nonsense Mutation 6, 3'Flank 4, Splice Region 4, Splice Site 3, 5'UTR 3, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHEB | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 36/180 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519950, COSV51262364, COSV51263550; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACADM | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs796051897; called by muse, mutect2
- ACTL7B | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1480803021; called by muse, mutect2
- ATAD2 | c.415G>T p.V139F | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.098); catalogued as COSV54881193; called by muse, mutect2, varscan2
- CPNE5 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as rs571508108; called by muse, mutect2
- DDX50 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104424183; called by muse, mutect2, varscan2
- DLG4 | c.926G>A p.R309Q (on ENST00000399506 / NM_001321075.3; = p.R352Q on NM_001365.4) | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs766960060; called by muse, mutect2, varscan2
- EFR3A | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs1359496595; called by muse, mutect2, varscan2
- ELAVL4 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1345370346, COSV63914597; called by muse, mutect2
- EMILIN2 | c.2086C>T p.Q696* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs758271770; called by muse, mutect2, varscan2
- GRIN3A | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62453111; called by muse, mutect2, varscan2
- H2AC17 | c.207C>G p.N69K | Missense Mutation (SNP) | VAF 51/382 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV58153758; called by muse, mutect2, varscan2
- HS3ST2 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 9/223 reads (4%) | catalogued as rs1336994762, COSV54457839; called by muse, mutect2
- IFNGR1 | c.1405G>T p.D469Y | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62992449; called by muse, mutect2, varscan2
- NUDT9 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772177208, COSV56198286; called by muse, mutect2, varscan2
- PAM | c.2627C>G p.P876R | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57216591; called by muse, mutect2, varscan2
- PASD1 | c.2107G>T p.V703F | Missense Mutation (SNP) | VAF 15/341 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1306096843; called by muse, mutect2
- SLC38A1 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV67064301; called by muse, mutect2, varscan2
- TFE3 | c.114C>A p.L38= | Splice Region (SNP) | VAF 31/139 reads (22%) | catalogued as COSV59946412; called by muse, mutect2, varscan2
- TFIP11 | c.1474A>T p.I492F | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV53226609; called by muse, mutect2, varscan2
- USP38 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761444526; called by muse, mutect2, varscan2
- VANGL2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759727082; called by muse, mutect2, varscan2
- ABCA1 | c.5935T>G p.S1979A | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2
- ACBD7 | c.156del p.G53Afs*30 | Frame Shift Del (DEL) | VAF 36/226 reads (16%) | called by mutect2, pindel, varscan2
- AKR1B1 | c.744C>A p.V248= | Splice Region (SNP) | VAF 59/463 reads (13%) | called by muse, mutect2, varscan2
- APH1A | c.749A>T p.D250V | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARHGEF19 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.376); called by muse, mutect2
- ASTN1 | c.1075del p.L359* | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | called by mutect2, pindel, varscan2
- BEND4 | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.092); called by muse, mutect2
- BRCC3 | c.98A>C p.E33A | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- C12orf40 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CAND1 | c.1126del p.S376Lfs*4 | Frame Shift Del (DEL) | VAF 28/263 reads (11%) | called by mutect2, pindel, varscan2
- CCDC149 | c.1217A>T p.D406V (on ENST00000635206 / NM_001330643.2; = p.D395V on NM_173463.5) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.945); called by muse, varscan2
- CCDC57 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CDCA2 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CLMN | c.2040G>T p.Q680H | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CSTF2T | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 38/259 reads (15%) | called by muse, mutect2, varscan2
- CYP2A6 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2
- DNAH5 | c.13491+1del p.X4497_splice | Splice Site (DEL) | VAF 42/286 reads (15%) | called by mutect2, pindel, varscan2
- EVI5 | c.1549A>G p.R517G | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FARP2 | c.1255_1259delinsTG p.L419_P420delins* | Nonsense Mutation (DEL) | VAF 33/266 reads (12%) | called by pindel, varscan2*
- FBRS | c.722del p.P241Lfs*63 (on ENST00000287468; = p.P761Lfs*63 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 18/161 reads (11%) | called by mutect2, pindel, varscan2
- FHAD1 | c.1138A>G p.K380E | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GGA3 | c.801del p.S267Rfs*43 (on ENST00000537686 / NM_138619.4; = p.S234Rfs*43 on NM_014001.5) | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.9581T>C p.I3194T | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- GPR35 | c.-10_-5+6del | Splice Site (DEL) | VAF 15/150 reads (10%) | called by mutect2, pindel
- GULP1 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HLA-E | c.775del p.D259Mfs*35 | Frame Shift Del (DEL) | VAF 60/488 reads (12%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.2530G>C p.V844L | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- KIF22 | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 43/395 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KNOP1 | c.459_462del p.E154Kfs*58 | Frame Shift Del (DEL) | VAF 30/187 reads (16%) | called by mutect2, pindel, varscan2
- LIPC | c.41T>C p.L14S | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- LYPD3 | c.382+4C>A | Splice Region (SNP) | VAF 84/453 reads (19%) | called by muse, mutect2, varscan2
- MAPK15 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- MED13 | c.2971G>T p.A991S | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- METTL1 | c.136T>C p.W46R | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MTHFD1L | c.1056del p.K352Nfs*52 | Frame Shift Del (DEL) | VAF 19/144 reads (13%) | called by mutect2, pindel, varscan2
- MUC17 | c.10990_10994del p.T3664Cfs*15 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- MYH7B | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- OMG | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOA | c.2187C>G p.D729E (on ENST00000286149; = p.D715E on NM_144672.4) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PCDHB6 | c.1348A>C p.T450P | Missense Mutation (SNP) | VAF 84/625 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PDAP1 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- PHF20 | c.361del p.Y121Mfs*4 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel
- PLCB2 | c.1487-2_1496delinsT p.X496_splice | Splice Site (DEL) | VAF 23/157 reads (15%) | called by pindel, varscan2*
- PLEKHA4 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POU3F2 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 99/637 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R16B | c.46A>T p.K16* | Nonsense Mutation (SNP) | VAF 35/176 reads (20%) | called by muse, mutect2, varscan2
- PRELP | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- RALGAPA2 | c.3652C>T p.L1218F | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGS14 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RXRA | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 95/462 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RYR2 | c.11177A>G p.Y3726C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SACS | c.8626G>A p.E2876K | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SBSPON | c.410_421delinsC p.V137Afs*33 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | called by pindel, varscan2*
- SDCCAG8 | c.824C>G p.T275S | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC1A5 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC6A14 | c.902C>G p.S301* | Nonsense Mutation (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- SPEM1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SPINK4 | c.216-5C>T | Splice Region (SNP) | VAF 23/151 reads (15%) | called by muse, mutect2, varscan2
- TAAR2 | c.88_89del p.N30* | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel*, varscan2
- TEDC1 | c.574dup p.L192Pfs*19 | Frame Shift Ins (INS) | VAF 25/137 reads (18%) | called by mutect2, pindel, varscan2
- TTC3 | c.5646T>G p.S1882R | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- WDR35 | c.414del p.V139* | Frame Shift Del (DEL) | VAF 36/214 reads (17%) | called by mutect2, pindel, varscan2
- ZMYND10 | c.356C>G p.T119R | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF385B | c.586C>G p.H196D | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF750 | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF91 | c.2312A>G p.K771R | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ZSCAN29 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 75/353 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- AKAP9 | c.6738G>A p.K2246= (on ENST00000359028; = p.K2222= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1262023240; called by muse, mutect2, varscan2
- CHRM4 | c.432C>T p.R144= | Silent (SNP) | VAF 29/404 reads (7%) | catalogued as rs1480749933; called by muse, mutect2
- FBN2 | c.3798C>T p.C1266= | Silent (SNP) | VAF 79/447 reads (18%) | called by muse, mutect2, varscan2
- FBXL6 | c.327G>T p.A109= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV100095477; called by muse, mutect2, varscan2
- FUT5 | c.147T>A p.L49= | Silent (SNP) | VAF 24/440 reads (5%) | called by muse, mutect2
- FZD9 | c.1248C>T p.F416= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV60669665; called by muse, mutect2, varscan2
- ITGB1BP1 | c.294T>C p.D98= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as rs201976301, COSV99432091; called by muse, mutect2, varscan2
- MANBA | c.1986A>G p.K662= (on ENST00000642252; = p.K616= on NM_005908.4) | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as CD065752; called by muse, mutect2, varscan2
- MED13 | c.2292T>C p.R764= | Silent (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- MUC6 | c.4662C>A p.T1554= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as rs755302968, COSV70143201; called by muse, mutect2, varscan2
- PIEZO2 | c.5670C>T p.H1890= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs866759573; called by muse, mutect2
- PLEK | c.427C>T p.L143= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99029643; called by muse, mutect2, varscan2
- SNX25 | c.1617T>C p.V539= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs1248221421; called by muse, mutect2, varscan2
- SPINT2 | c.210C>T p.G70= | Silent (SNP) | VAF 65/426 reads (15%) | called by muse, mutect2, varscan2
- AC009053.1 | chr16:74336615 C>T | 3'Flank (SNP) | VAF 24/440 reads (5%) | called by muse, mutect2
- AC009053.1 | chr16:74336616 C>A | 3'Flank (SNP) | VAF 24/436 reads (6%) | called by muse, mutect2
- ACSF3 | c.*1355T>C | 3'UTR (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
- AQP3 | c.-42C>A | 5'UTR (SNP) | VAF 15/88 reads (17%) | called by muse, varscan2
- BAG1 | c.*154G>A | 3'UTR (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- CC2D1B | c.*386_*391del | 3'UTR (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- CCL4L2 | c.*202C>T | 3'UTR (SNP) | VAF 54/125 reads (43%) | called by muse, mutect2, varscan2
- CEACAM21 | c.-4G>A | 5'UTR (SNP) | VAF 34/197 reads (17%) | catalogued as rs1489304664; called by muse, mutect2, varscan2
- CELP | chr9:133086294 C>G | 3'Flank (SNP) | VAF 33/241 reads (14%) | called by muse, mutect2, varscan2
- DCAF17 | c.*602T>C | 3'UTR (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- DLGAP4 | c.1648+15587_1648+15588del | Intron (DEL) | VAF 39/225 reads (17%) | called by mutect2, pindel, varscan2
- DTWD2 | c.218+13656_218+13657del | Intron (DEL) | VAF 10/104 reads (10%) | called by pindel, varscan2
- FAM205BP | n.923G>T | RNA (SNP) | VAF 66/466 reads (14%) | called by muse, mutect2, varscan2
- FBRS | chr16:30662466 A>G | 5'Flank (SNP) | VAF 29/205 reads (14%) | called by muse, mutect2, varscan2
- METTL15 | c.779-2272C>T | Intron (SNP) | VAF 9/63 reads (14%) | catalogued as rs768331835; called by muse, mutect2, varscan2
- MYH3 | c.348+28C>T | Intron (SNP) | VAF 44/331 reads (13%) | called by muse, mutect2, varscan2
- SPG7 | c.1642+1113del | Intron (DEL) | VAF 21/128 reads (16%) | called by mutect2, pindel, varscan2
- TFEC | c.-4T>C | 5'UTR (SNP) | VAF 43/260 reads (17%) | called by muse, mutect2, varscan2
- TIA1 | c.310+30A>G | Intron (SNP) | VAF 10/56 reads (18%) | called by muse, varscan2
- TSBP1 | chr6:32288627 C>A | 3'Flank (SNP) | VAF 7/137 reads (5%) | called by muse, mutect2
- TSC22D1 | c.*600G>C | 3'UTR (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- VEGFA | c.119-15_119-14dup | Intron (INS) | VAF 53/517 reads (10%) | called by mutect2, pindel, varscan2
